TARGET case TARGET-30-PALWVJ — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Adrenal gland. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/b4f7373c-f32c-5b6b-bbde-add5f43a0adf

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 4 years; Vital status: Dead; Days to death: 803 days (2.2 years).

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; ICD-10 code: C74.1; Tissue or organ of origin: Medulla of adrenal gland; Classification of tumor: primary; Age at diagnosis: 4.2 years (1,544 days); Year of diagnosis: 2002; Days to last follow up: 803 days (2.2 years); Cog neuroblastoma risk group: High Risk; Inpc grade: Undifferentiated or Poorly Differentiated; INSS stage: Stage 4; Mitosis karyorrhexis index: Intermediate.
   Pathology details: Necrosis percent: 60; Percent tumor nuclei: 40.
   Treatment given: Protocol identifier: ANBL00B1.

Follow-up (2 entries)
- Days to follow up: 417 days (1.1 years); Progression or recurrence anatomic site: Bone marrow; Days to first event: 417 days (1.1 years); First event: Relapse.
- Days to follow up: 803 days (2.2 years); Year of follow up: 2004.

Molecular and laboratory tests
- MYCN amplification: Not Amplified.
- Test: Abnormal, NOS; Ploidy: Hyperdiploid.

Biospecimens (3 samples)
- Samples TARGET-30-PALWVJ-01A, TARGET-30-PALWVJ-01B (2 with the same recorded description): Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-30-PALWVJ-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_NBL_ClinicalData_Discovery_20230523.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 803
- Ploidy: Hyperdiploid (DI>1)
- Ploidy Value: 1.88
- Histology: Unfavorable
- Percent Tumor v/s Stroma: 90/10
